Somatic mutation profile of tumor specimen TCGA-XE-AAO6-01A (aliquot TCGA-XE-AAO6-01A-31D-A435-10) from TCGA case TCGA-XE-AAO6, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 47.7 years (17,417 days).
Specimen TCGA-XE-AAO6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef2c06fd-c08e-41ca-9d16-324664aec9a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AAO6-10A (Blood Derived Normal), aliquot TCGA-XE-AAO6-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63f77591-daed-4e9c-84f8-a564124ea049

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 36/197 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CD320 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV100035849; called by muse, mutect2, varscan2
- DHRS7C | c.280C>T p.P94S (on ENST00000330255 / NM_001220493.2; = p.P93S on NM_001105571.3) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs767153024, COSV99042644; called by muse, mutect2, varscan2
- DNAI4 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs949497667, COSV64021802; called by muse, mutect2, varscan2
- TMEM176A | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.664); catalogued as rs760277433; called by muse, mutect2
- CACNA1C | c.5015A>C p.D1672A | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CPT2 | c.1556_1557del p.E519Afs*8 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- HERPUD2 | c.948dup p.A317Sfs*7 | Frame Shift Ins (INS) | VAF 22/158 reads (14%) | called by mutect2, pindel, varscan2
- IGHV3-53 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- KIF3C | c.1542C>G p.Y514* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- KIRREL1 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KLC4 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIEF2 | c.1063C>G p.R355G | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.926); called by muse, mutect2
- SHE | c.997_999del p.K333del | In Frame Del (DEL) | VAF 20/144 reads (14%) | called by pindel, varscan2
- USP13 | c.963G>C p.Q321H | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM71E2 | c.1764G>T p.P588= | Silent (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2
- RAB3GAP2 | c.2832G>A p.K944= | Silent (SNP) | VAF 35/198 reads (18%) | catalogued as rs1327616232; called by muse, mutect2, varscan2
- SPECC1L | c.1131A>T p.I377= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs551676689; called by muse, mutect2, varscan2
- ZNF429 | c.-21G>A | 5'UTR (SNP) | VAF 11/56 reads (20%) | catalogued as rs765494665; called by muse, mutect2, varscan2
